Somatic mutation profile of tumor specimen TCGA-AB-2884-03A (aliquot TCGA-AB-2884-03A-01W-0732-08) from TCGA case TCGA-AB-2884, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia without maturation; Tissue or organ of origin: Bone marrow; Age at diagnosis: 44.6 years (16,285 days).
Specimen TCGA-AB-2884-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0937bc7e-6559-4abc-862c-410a46af90f2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AB-2884-11A (Solid Tissue Normal), aliquot TCGA-AB-2884-11A-01W-0732-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/649e0efb-1878-41d4-b605-c9597f36be4f

The open-access MAF lists 1 somatic variant for this specimen: 1 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EDEM2 | c.98C>T p.A33V | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.031); catalogued as COSV65713289; called by muse, mutect2, varscan2
